Somatic mutation profile of tumor specimen TARGET-10-PAREWM-09A (aliquot TARGET-10-PAREWM-09A-01D) from TARGET case TARGET-10-PAREWM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,471 days).
Specimen TARGET-10-PAREWM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96a98d9e-dbeb-41eb-9658-83570ada3ca2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREWM-10A (Blood Derived Normal), aliquot TARGET-10-PAREWM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddb25878-d6e5-486b-a03b-dae9cb630d6f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV52187684; called by muse, mutect2, varscan2
- JAKMIP1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759478347; called by muse, mutect2
- SLC13A4 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs572670318, COSV62461563; called by muse, mutect2, varscan2
- ZNF799 | c.1156A>T p.M386L | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as rs770678785; called by muse, mutect2, varscan2
- SFXN2 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GPR146 | c.387C>A p.I129= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as COSV52467503; called by muse, mutect2, varscan2
- NCOR2 | c.5404C>A p.R1802= | Silent (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
